Gene-level copy-number profile of tumor specimen AP-E98M-NL from APOLLO case AP-E98M, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-E98M-NL: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4dd1cf30-40d8-4064-85c6-479cf220ea37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-E98M-QT (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/7f23f02e-4542-48b7-80b9-7ef4389d13d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 11,822; copy number 2: 42,023; copy number 3: 3,659; copy number 4: 551; copy number 5: 26; copy number 7: 11; copy number 9: 19; copy number 10: 25; copy number 11: 26; copy number 12: 23; copy number 13: 19; copy number 16: 16; copy number 22: 25.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr4:173,615,936–173,634,371, 2 genes: MORF4, RANP6.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr13:19,262,797–19,783,019, 17 genes (within-gene range 0–1): ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P.
- chr13:20,564,708–20,723,098, 7 genes: AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2.
- chr13:20,747,035–20,748,057, 1 gene (within-gene range 0–1): RANP8.
- chr13:49,187,479–49,187,670, 1 gene (within-gene range 0–1): COX7CP1.
- chr16:34,266,041–35,912,516, 81 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–1,856,156, 69 genes, copy number 7–12 (broad region; genes not listed).
- chr4:4,048,211–4,419,058, 14 genes, copy number 5 (within-gene range 2–5): AC116562.3, RPS3AP16, AC116562.2, AC116562.1, OR7E103P, UNC93B4, OR7E99P, OR7E43P, OTOP1, TMEM128, LYAR, ZBTB49, AC105415.1, NSG1.
- chr5:58,198–4,874,759, 98 genes, copy number 5–22 (broad region; genes not listed).
- chr5:36,861,736–36,867,238, 1 gene, copy number 5: AC026741.1.
- chr5:163,855,140–164,234,097, 4 genes, copy number 5: AC008432.1, LSM1P2, AC008662.1, AC008662.2.
- chr5:165,905,126–166,382,599, 4 genes, copy number 5: AC008489.1, RPL7P20, AC114321.1, AC026403.1.

Autosomal genes at a single copy (total copy number 1): 11,812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
